Somatic mutation profile of tumor specimen C3N-02695-01 (aliquot CPT0244940010) from CPTAC case C3N-02695, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 45.6 years (16,652 days).
Specimen C3N-02695-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 352b9a19-c9b2-4843-b092-5cfa5087476c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02695-31 (Blood Derived Normal), aliquot CPT0245000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a94940b-61a5-49cc-80d5-21ae24028c89

The open-access MAF lists 125 somatic variants for this specimen: 91 protein-altering or splice-affecting, 24 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 24, 3'UTR 5, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Splice Site 2, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 292/732 reads (40%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761584848, COSV55950092; called by muse, mutect2
- ADRA1D | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 101/809 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs61759840, COSV65242435; called by muse, mutect2, varscan2
- AFF1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs759273880; called by muse, mutect2, varscan2
- CSF2RA | c.869C>A p.A290E | Missense Mutation (SNP) | VAF 106/556 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV62624468; called by muse, mutect2, varscan2
- DICER1 | c.5552G>A p.R1851H | Missense Mutation (SNP) | VAF 39/707 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1426678586, COSV100602685, COSV58617823; ClinVar: uncertain significance; called by muse, mutect2
- DMBT1 | c.3088G>A p.V1030I (on ENST00000338354 / NM_001377530.1; = p.V531I on NM_004406.3) | Missense Mutation (SNP) | VAF 265/1208 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs368405942; called by muse, mutect2, varscan2
- DNMT1 | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 26/822 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61585005; called by muse, mutect2
- DUS2 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 23/636 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1425231629, COSV62708552; called by muse, mutect2
- ENPP7 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 52/1014 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs781876318; called by muse, mutect2
- EPHA7 | c.2403G>T p.R801S | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65189697; called by muse, mutect2
- FBRSL1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as rs970209591; called by muse, mutect2, varscan2
- FDXR | c.962G>A p.R321Q (on ENST00000293195 / NM_024417.5; = p.R327Q on NM_004110.6) | Missense Mutation (SNP) | VAF 24/533 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1179210362, COSV53109690; called by muse, mutect2
- FGB | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs772014512, COSV57417348; called by muse, mutect2, varscan2
- FGFR4 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs150920445; called by muse, mutect2
- GIMAP1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs374968861, COSV56188394; called by muse, mutect2, varscan2
- HPSE2 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV65203035; called by muse, mutect2, varscan2
- KLHL32 | c.1064T>A p.V355D | Missense Mutation (SNP) | VAF 28/718 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1250583094; called by muse, mutect2
- LGR6 | c.1897G>A p.G633R (on ENST00000367278 / NM_001017403.1; = p.G581R on NM_021636.3) | Missense Mutation (SNP) | VAF 22/503 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916794548, COSV55166949, COSV99707620; called by muse, mutect2
- NHSL1 | c.676+5G>A | Splice Region (SNP) | VAF 17/319 reads (5%) | catalogued as rs1414746965; called by muse, mutect2
- NMNAT3 | c.756C>G p.S252R (on ENST00000296202 / NM_001320512.1; = p.S215R on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs974556467; called by muse, mutect2
- PCK2 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 50/610 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763901019, COSV53750022; called by muse, mutect2
- POLR1E | c.841+1G>A p.X281_splice (on ENST00000377792 / NM_001282766.1; = p.X219_splice on NM_022490.4) | Splice Site (SNP) | VAF 32/364 reads (9%) | catalogued as rs200297662; called by muse, mutect2
- QRICH2 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 218/564 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as COSV53152731; called by muse, mutect2, varscan2
- SLCO5A1 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 51/971 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs769774098, COSV52656016; called by muse, mutect2
- SPEN | c.8713G>A p.D2905N | Missense Mutation (SNP) | VAF 16/545 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1456771008, COSV65358945; called by muse, mutect2
- SREBF1 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 98/1241 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1450285069, COSV55419276; called by muse, mutect2
- TNFAIP8L2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 122/556 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs935731135, COSV100925292; called by muse, mutect2, varscan2
- TTC37 | c.4480C>T p.R1494C | Missense Mutation (SNP) | VAF 27/459 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs373485467; called by muse, mutect2
- ZCCHC12 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1424181652, COSV104402607; called by muse, mutect2
- ZNF479 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100482899; called by muse, mutect2
- ZNF664 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 75/343 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV61877449; called by muse, mutect2, varscan2
- ABCC6 | c.1541T>A p.V514D | Missense Mutation (SNP) | VAF 39/1404 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AGL | c.3122C>T p.S1041L | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2
- ALDH2 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- APOB | c.3620A>G p.Y1207C | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ATMIN | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 19/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CD1E | c.1132A>T p.K378* | Nonsense Mutation (SNP) | VAF 50/285 reads (18%) | called by muse, mutect2, varscan2
- CHL1 | c.1687G>A p.G563S (on ENST00000397491 / NM_001253387.1; = p.G579S on NM_006614.4) | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2
- CRLF3 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 9/281 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- CRYBG3 | c.6326del p.G2109Afs*26 | Frame Shift Del (DEL) | VAF 54/268 reads (20%) | called by mutect2, varscan2
- CRYBG3 | c.6326G>C p.G2109A | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- DBX2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- DCP1B | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- DNMT3B | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 40/1024 reads (4%) | called by muse, mutect2
- DOCK2 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM43B | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 63/1042 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FFAR4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 43/768 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.012); called by muse, mutect2
- FRMD4B | c.1521T>A p.F507L | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- GADD45G | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 188/442 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GLYATL3 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 32/874 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- GSDMA | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 115/319 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- HASPIN | c.751T>G p.S251A | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); called by muse, mutect2
- HNRNPR | c.1756C>A p.R586S | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- IRAG1 | c.1670A>C p.Q557P | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- KRT6A | c.1145C>G p.A382G | Missense Mutation (SNP) | VAF 236/1216 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- LRRTM3 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2
- MDH1B | c.1061T>C p.V354A | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2
- MKI67 | c.3222G>C p.Q1074H | Missense Mutation (SNP) | VAF 55/872 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MLEC | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 74/444 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MTIF2 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MUC16 | c.42143A>G p.E14048G | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NANOS3 | c.380C>T p.S127L (on ENST00000397555; = p.S146L on NM_001098622.2) | Missense Mutation (SNP) | VAF 126/543 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NKAIN4 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 22/703 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NKX1-1 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated, low confidence (0.16); called by muse, mutect2
- NOTCH3 | c.1025T>A p.M342K | Missense Mutation (SNP) | VAF 107/979 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- OR8G2P | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2
- PAX6 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 36/936 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2
- PC | c.1064G>T p.R355M | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2
- PCDHB12 | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 62/1278 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDIA3 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); called by muse, mutect2
- PRAMEF27 | c.1360T>A p.F454I | Missense Mutation (SNP) | VAF 137/841 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREX1 | c.3155C>A p.P1052Q | Missense Mutation (SNP) | VAF 263/1255 reads (21%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAVER2 | c.1423A>T p.I475F (on ENST00000294428 / NM_001366165.1; = p.I462F on NM_018211.4) | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, varscan2
- REV3L | c.1200T>G p.S400R | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2
- REXO5 | c.250del p.S84Afs*11 | Frame Shift Del (DEL) | VAF 104/445 reads (23%) | called by mutect2, pindel, varscan2
- RPS6KA6 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SECISBP2L | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 15/510 reads (3%) | called by muse, mutect2
- SERPINB12 | c.889C>A p.L297M | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2
- SFMBT2 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- SPATA7 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- SPEF2 | c.1775C>G p.T592S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2
- TBX22 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TMPRSS3 | c.573-1G>C p.X191_splice | Splice Site (SNP) | VAF 20/590 reads (3%) | called by muse, mutect2
- TRIM45 | c.1377del p.D459Efs*37 | Frame Shift Del (DEL) | VAF 58/235 reads (25%) | called by mutect2, pindel, varscan2
- TRO | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPV4 | c.362A>T p.K121M | Missense Mutation (SNP) | VAF 46/706 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2
- UNC5C | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- VEZF1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- ZNF781 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2
- ZNF862 | c.3017C>T p.S1006F | Missense Mutation (SNP) | VAF 25/654 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CLMN | c.2370C>T p.L790= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as rs1227886874; called by muse, mutect2, varscan2
- EPB41L4B | c.1507A>C p.R503= | Silent (SNP) | VAF 277/1399 reads (20%) | called by muse, mutect2, varscan2
- ERBB4 | c.3433C>T p.L1145= | Silent (SNP) | VAF 26/452 reads (6%) | catalogued as rs774192228; called by muse, mutect2
- FAM43B | c.132G>C p.L44= | Silent (SNP) | VAF 66/1045 reads (6%) | called by muse, mutect2
- GABRG2 | c.1393C>A p.R465= (on ENST00000361925 / NM_001375343.1; = p.R425= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/694 reads (4%) | catalogued as COSV62723646; called by muse, mutect2
- IQSEC3 | c.1248G>A p.A416= (on ENST00000538872 / NM_001170738.2; = p.A113= on NM_015232.1) | Silent (SNP) | VAF 34/602 reads (6%) | catalogued as rs148393504; called by muse, mutect2
- IRF9 | c.930C>T p.G310= | Silent (SNP) | VAF 70/183 reads (38%) | called by muse, mutect2, varscan2
- LRRK2 | c.7314T>C p.D2438= | Silent (SNP) | VAF 18/329 reads (5%) | called by muse, mutect2
- MAN1A1 | c.415C>T p.L139= | Silent (SNP) | VAF 34/567 reads (6%) | called by muse, mutect2
- MBP | c.369C>T p.D123= | Silent (SNP) | VAF 18/274 reads (7%) | catalogued as COSV100592443; called by muse, mutect2
- MYO9B | c.5685C>T p.I1895= | Silent (SNP) | VAF 14/375 reads (4%) | called by muse, mutect2
- NEURL4 | c.3600G>A p.R1200= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as rs1335253813; called by muse, mutect2
- PCDHB8 | c.1956G>A p.P652= | Silent (SNP) | VAF 72/1632 reads (4%) | catalogued as rs782285661, COSV50767905; called by muse, mutect2
- PODN | c.1770C>T p.F590= (on ENST00000395871; = p.F542= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/465 reads (4%) | catalogued as rs1276343948, COSV57012423; called by muse, mutect2
- PSMB6 | c.24T>G p.A8= | Silent (SNP) | VAF 76/600 reads (13%) | called by muse, mutect2, varscan2
- PTPRS | c.5319G>A p.S1773= | Silent (SNP) | VAF 30/498 reads (6%) | catalogued as rs1445335545; called by muse, mutect2
- RAD23A | c.657G>A p.S219= | Silent (SNP) | VAF 59/911 reads (6%) | catalogued as rs199799122; called by muse, mutect2
- RPS15 | c.21G>A p.K7= | Silent (SNP) | VAF 31/1080 reads (3%) | called by muse, mutect2
- SEMA6A | c.1002C>T p.D334= | Silent (SNP) | VAF 14/305 reads (5%) | catalogued as rs1264649383; called by muse, mutect2
- SLC15A4 | c.621C>A p.I207= | Silent (SNP) | VAF 19/374 reads (5%) | catalogued as rs886654391; called by muse, mutect2
- TIGD1 | c.939G>A p.E313= | Silent (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- TONSL | c.645G>A p.A215= | Silent (SNP) | VAF 26/440 reads (6%) | catalogued as rs746597830; called by muse, mutect2
- TRIM77 | c.48G>T p.S16= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV101242258; called by muse, mutect2, varscan2
- TTN | c.21303A>T p.P7101= (on ENST00000591111; = p.P6174= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV59944464; called by muse, mutect2
- ATP11C | c.-14C>T | 5'UTR (SNP) | VAF 40/193 reads (21%) | catalogued as rs1428830903; called by muse, mutect2, varscan2
- CCSER2 | c.*92G>T | 3'UTR (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- CPLANE1 | c.*3484C>T | 3'UTR (SNP) | VAF 16/487 reads (3%) | called by muse, mutect2
- FAM76B | c.88-403A>T | Intron (SNP) | VAF 31/218 reads (14%) | catalogued as rs1394087980; called by muse, mutect2, varscan2
- GYPB | c.*38C>G | 3'UTR (SNP) | VAF 26/414 reads (6%) | catalogued as COSV51622919; called by muse, mutect2
- HERC2P3 | n.1410C>A | RNA (SNP) | VAF 68/2436 reads (3%) | called by muse, mutect2
- OSBPL2 | c.-31G>A | 5'UTR (SNP) | VAF 90/496 reads (18%) | called by muse, mutect2, varscan2
- PCMT1 | c.*58A>T | 3'UTR (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- PDE4D | c.42+37770G>T | Intron (SNP) | VAF 44/196 reads (22%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.*7_*26del | 3'UTR (DEL) | VAF 49/143 reads (34%) | called by mutect2, pindel
